Somatic mutation profile of tumor specimen C3N-03228-03 (aliquot CPT0180070006) from CPTAC case C3N-03228, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 31.2 years (11,393 days).
Specimen C3N-03228-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 10f12676-709a-4006-94b6-d20092805f15.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03228-71 (Blood Derived Normal), aliquot CPT0180170002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/77468275-623f-4e78-ac89-4ecb0cf98bbf

The open-access MAF lists 389 somatic variants for this specimen: 248 protein-altering or splice-affecting, 125 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 228, Silent 125, Nonsense Mutation 14, Intron 10, Splice Region 4, 5'Flank 3, RNA 2, Splice Site 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SCN9A | c.2521C>T p.R841* (on ENST00000303354; = p.R830* on NM_002977.3) | Nonsense Mutation (SNP) | VAF 34/219 reads (16%) | catalogued as rs780673293, CM072032; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.2087C>T p.S696F | Missense Mutation (SNP) | VAF 32/208 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55947943; called by muse, mutect2, varscan2
- ABCB5 | c.2489C>T p.S830F (on ENST00000404938 / NM_001163941.2; = p.S385F on NM_178559.6) | Missense Mutation (SNP) | VAF 101/549 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs866781790, COSV51705583; called by muse, mutect2, varscan2
- AC013477.1 | c.2329C>T p.H777Y | Missense Mutation (SNP) | VAF 107/347 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.929); catalogued as rs202190211; called by muse, mutect2, varscan2
- ACP7 | c.1174G>A p.V392M | Missense Mutation (SNP) | VAF 137/446 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs765621050; called by muse, mutect2, varscan2
- ACTN1 | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 54/127 reads (43%) | catalogued as rs368332884; called by muse, mutect2, varscan2
- ADAM23 | c.2167C>T p.R723W | Missense Mutation (SNP) | VAF 71/368 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100007905; called by muse, mutect2, varscan2
- ADAM7 | c.905G>A p.G302E | Missense Mutation (SNP) | VAF 104/297 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51535001; called by muse, mutect2, varscan2
- ADGRB1 | c.4247C>T p.P1416L | Missense Mutation (SNP) | VAF 53/145 reads (37%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1424454036; called by muse, mutect2, varscan2
- AP3B1 | c.2587C>T p.P863S | Missense Mutation (SNP) | VAF 49/291 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.335); catalogued as rs1056281695, COSV54892980; called by muse, mutect2, varscan2
- APOB | c.6080C>A p.P2027Q | Missense Mutation (SNP) | VAF 144/361 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs892830346; called by muse, mutect2, varscan2
- APOB | c.5755C>T p.L1919F | Missense Mutation (SNP) | VAF 151/384 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.184); catalogued as rs775995065, COSV51921685; called by muse, mutect2, varscan2
- ARHGAP36 | c.1601G>T p.R534L | Missense Mutation (SNP) | VAF 132/235 reads (56%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.045); catalogued as rs376197707, COSV52265119; called by muse, mutect2, varscan2
- BHMT2 | c.752G>A p.G251E | Missense Mutation (SNP) | VAF 81/274 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376553846; called by muse, mutect2, varscan2
- BRINP2 | c.1238C>T p.S413F | Missense Mutation (SNP) | VAF 91/227 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as COSV64177436; called by muse, mutect2, varscan2
- C16orf78 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 99/284 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.071); catalogued as rs373806217; called by muse, mutect2, varscan2
- CASR | c.2068G>A p.E690K (on ENST00000490131; = p.E767K on NM_000388.4) | Missense Mutation (SNP) | VAF 124/360 reads (34%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.994); catalogued as CM050191, CM106568, COSV56136585, COSV99949724; called by muse, mutect2, varscan2
- CCBE1 | c.213G>A p.R71= | Splice Region (SNP) | VAF 45/183 reads (25%) | catalogued as COSV101232766; called by muse, mutect2, varscan2
- CCDC74B | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 29/169 reads (17%) | SIFT tolerated (1); PolyPhen probably damaging (0.988); catalogued as COSV100134334; called by muse, mutect2, varscan2
- CCP110 | c.1423C>T p.H475Y | Missense Mutation (SNP) | VAF 91/278 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.134); catalogued as COSV66818215; called by muse, mutect2, varscan2
- CD1B | c.346G>A p.G116S | Missense Mutation (SNP) | VAF 161/390 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.087); catalogued as COSV100939229; called by muse, mutect2, varscan2
- CD1E | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 349/506 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as rs867813346, COSV63770393; called by muse, mutect2, varscan2
- CDK5 | c.517C>T p.L173F | Missense Mutation (SNP) | VAF 53/367 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99876814; called by muse, mutect2, varscan2
- CEP250 | c.6896C>T p.T2299I | Missense Mutation (SNP) | VAF 68/273 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV100698784; called by muse, mutect2, varscan2
- CHAT | c.1274C>T p.S425F | Missense Mutation (SNP) | VAF 105/286 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100340197; called by muse, mutect2, varscan2
- CHD6 | c.8057C>T p.A2686V | Missense Mutation (SNP) | VAF 131/468 reads (28%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.01); catalogued as rs1325666386; called by muse, varscan2
- CHSY3 | c.1876C>T p.P626S | Missense Mutation (SNP) | VAF 87/313 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV59286644; called by muse, mutect2, varscan2
- CLEC4D | c.62C>T p.S21L | Missense Mutation (SNP) | VAF 93/247 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs143281343; called by muse, mutect2, varscan2
- CLK3 | c.392G>A p.R131K | Missense Mutation (SNP) | VAF 137/352 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs1166587974, COSV61414220; called by muse, mutect2, varscan2
- COL4A2 | c.2849G>A p.G950E | Missense Mutation (SNP) | VAF 257/522 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64628883; called by muse, mutect2, varscan2
- CSMD1 | c.2531T>A p.F844Y (on ENST00000520002; = p.F843Y on NM_033225.6) | Missense Mutation (SNP) | VAF 52/375 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs1453409610; called by muse, mutect2
- CSMD2 | c.1949G>A p.G650E | Missense Mutation (SNP) | VAF 145/477 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs868169530, COSV53878136; called by muse, mutect2, varscan2
- DCST1 | c.127G>A p.G43S | Missense Mutation (SNP) | VAF 379/535 reads (71%) | SIFT tolerated (0.16); PolyPhen benign (0.433); catalogued as COSV55053789; called by muse, mutect2, varscan2
- DGKB | c.1418G>A p.G473E | Missense Mutation (SNP) | VAF 170/339 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.09); catalogued as rs533895069, COSV51791441; called by muse, mutect2, varscan2
- DNAH5 | c.9023G>A p.G3008E | Missense Mutation (SNP) | VAF 124/280 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54208650; called by muse, mutect2, varscan2
- DNAH8 | c.11389C>T p.P3797S | Missense Mutation (SNP) | VAF 82/284 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); catalogued as rs762008200, COSV59460765; called by muse, mutect2, varscan2
- DSG1 | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 92/308 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as rs78287742; called by muse, mutect2, varscan2
- E4F1 | c.1861C>T p.L621F | Missense Mutation (SNP) | VAF 179/542 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.742); catalogued as rs867738057; called by muse, mutect2, varscan2
- ERN1 | c.2871C>G p.F957L | Missense Mutation (SNP) | VAF 343/642 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV70501740; called by muse, mutect2, varscan2
- EXOSC10 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 49/317 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.067); catalogued as COSV58663767; called by muse, mutect2, varscan2
- FAM135B | c.2414G>A p.S805N | Missense Mutation (SNP) | VAF 104/423 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1225278509, COSV52753341; called by muse, mutect2, varscan2
- FAM91A1 | c.1693C>T p.Q565* | Nonsense Mutation (SNP) | VAF 39/263 reads (15%) | catalogued as COSV58237144; called by muse, mutect2, varscan2
- FCN2 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 143/265 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV99391478; called by muse, mutect2, varscan2
- FCRL4 | c.1346C>T p.S449L | Missense Mutation (SNP) | VAF 249/361 reads (69%) | SIFT tolerated (0.7); PolyPhen benign (0.03); catalogued as rs777588327, COSV54863730; called by muse, mutect2, varscan2
- FGF6 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 55/195 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV57404795; called by muse, mutect2, varscan2
- GLI3 | c.1096C>T p.R366* | Nonsense Mutation (SNP) | VAF 72/656 reads (11%) | catalogued as HM971692, COSV67889135; called by muse, mutect2, varscan2
- GPR179 | c.3190G>A p.E1064K (on ENST00000621958; = p.E1063K on NM_001004334.4) | Missense Mutation (SNP) | VAF 125/469 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.077); catalogued as rs767717060; called by muse, mutect2, varscan2
- GRIA2 | c.645A>C p.K215N | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.869); catalogued as COSV52385939; called by mutect2, varscan2
- GRID2 | c.1129G>A p.G377R | Missense Mutation (SNP) | VAF 47/186 reads (25%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as rs75576544; called by muse, mutect2, varscan2
- GUCY1A1 | c.454C>T p.L152F | Missense Mutation (SNP) | VAF 40/352 reads (11%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.983); catalogued as COSV56656140; called by muse, mutect2, varscan2
- IDO2 | c.424G>A p.D142N (on ENST00000389060; = p.D155N on NM_194294.2) | Missense Mutation (SNP) | VAF 101/244 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.06); catalogued as COSV58424151; called by muse, mutect2, varscan2
- IDUA | c.920C>T p.S307F | Missense Mutation (SNP) | VAF 139/433 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs113373271; called by muse, varscan2
- IFI44L | c.932C>T p.S311F | Missense Mutation (SNP) | VAF 42/355 reads (12%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.971); catalogued as rs779446092; called by muse, mutect2, varscan2
- IGKV1-33 | c.143G>A p.S48N | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs766995671; called by muse, mutect2, varscan2
- IGSF21 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 89/255 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV52127045, COSV52131426; called by muse, mutect2, varscan2
- ITGA8 | c.586G>A p.G196S | Missense Mutation (SNP) | VAF 95/202 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100959608; called by muse, mutect2, varscan2
- IZUMO1 | c.322G>A p.V108M | Missense Mutation (SNP) | VAF 70/221 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs151047643; called by muse, mutect2, varscan2
- KLF3 | c.299C>T p.S100F | Missense Mutation (SNP) | VAF 171/458 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.328); catalogued as COSV54710278; called by muse, mutect2, varscan2
- KLK9 | c.196A>C p.K66Q | Missense Mutation (SNP) | VAF 35/290 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs760649897; called by muse, mutect2, varscan2
- KRT6C | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 158/492 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs371638126; called by muse, mutect2, varscan2
- KRT76 | c.1324G>A p.D442N | Missense Mutation (SNP) | VAF 105/365 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1049857440; called by muse, mutect2, varscan2
- L1TD1 | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 112/338 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as rs1158773471, COSV63133507; called by muse, mutect2, varscan2
- LAMB1 | c.1775C>T p.P592L | Missense Mutation (SNP) | VAF 60/318 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs753005293; called by muse, mutect2, varscan2
- LINGO1 | c.1837C>T p.R613C | Missense Mutation (SNP) | VAF 76/196 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1196875098; called by muse, mutect2, varscan2
- LZTS2 | c.763G>A p.G255R | Missense Mutation (SNP) | VAF 137/483 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.275); catalogued as rs778276719; called by muse, mutect2, varscan2
- LZTS2 | c.764G>A p.G255E | Missense Mutation (SNP) | VAF 141/488 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.19); catalogued as rs1238630580; called by muse, mutect2, varscan2
- MAGI3 | c.1786C>T p.P596S | Missense Mutation (SNP) | VAF 39/301 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100290553; called by muse, mutect2, varscan2
- MCM9 | c.1495C>T p.R499C | Missense Mutation (SNP) | VAF 77/153 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.432); catalogued as rs939087744, COSV60326805; called by muse, mutect2, varscan2
- MGAM | c.2675A>C p.K892T | Missense Mutation (SNP) | VAF 98/256 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV72073972; called by muse, mutect2, varscan2
- MUC16 | c.19387G>A p.D6463N | Missense Mutation (SNP) | VAF 79/268 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.009); catalogued as rs757804577, COSV67469344; called by muse, mutect2, varscan2
- MUC16 | c.19386G>A p.W6462* | Nonsense Mutation (SNP) | VAF 78/268 reads (29%) | catalogued as COSV67488299; called by muse, mutect2, varscan2
- MUC16 | c.13579G>A p.D4527N | Missense Mutation (SNP) | VAF 101/312 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.412); catalogued as COSV67451243; called by muse, mutect2, varscan2
- MYEF2 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 50/275 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV99981949; called by muse, mutect2, varscan2
- NPEPL1 | c.1403C>T p.P468L | Missense Mutation (SNP) | VAF 108/340 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs775915111, COSV100622658; called by muse, mutect2, varscan2
- NRK | c.3655G>A p.G1219R | Missense Mutation (SNP) | VAF 77/125 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99687171; called by muse, mutect2, varscan2
- NTNG1 | c.884G>A p.G295E | Missense Mutation (SNP) | VAF 62/224 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53984289; called by muse, mutect2, varscan2
- OR10AC1 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 80/428 reads (19%) | SIFT deleterious, low confidence (0); catalogued as rs1234817829; called by muse, varscan2
- OR5W2 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 101/260 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.098); catalogued as COSV60617296; called by muse, mutect2, varscan2
- PAG1 | c.968C>T p.P323L | Missense Mutation (SNP) | VAF 74/210 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.295); catalogued as rs763112241, COSV55062738; called by muse, mutect2, varscan2
- PALLD | c.2057G>A p.R686Q | Missense Mutation (SNP) | VAF 71/324 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1031710807, COSV54990164; called by muse, mutect2, varscan2
- PCDHGB1 | c.2078C>T p.A693V | Missense Mutation (SNP) | VAF 53/399 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.902); catalogued as rs1207518184, COSV54049007; called by muse, mutect2, varscan2
- PEAK3 | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 43/294 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.077); catalogued as COSV59233290; called by muse, mutect2, varscan2
- PEG3 | c.1486C>T p.Q496* | Nonsense Mutation (SNP) | VAF 116/402 reads (29%) | catalogued as COSV55630952; called by muse, mutect2, varscan2
- PEG3 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 107/320 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as COSV55626356, COSV99687015; called by mutect2, varscan2
- PHACTR1 | c.1610G>A p.R537K | Missense Mutation (SNP) | VAF 102/370 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs563759516; called by muse, mutect2, varscan2
- PRKAR2B | c.1176G>A p.M392I | Missense Mutation (SNP) | VAF 109/345 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as rs79974757; called by muse, mutect2, varscan2
- PSG11 | c.84G>A p.W28* | Nonsense Mutation (SNP) | VAF 67/236 reads (28%) | catalogued as rs1441148174, COSV60455181; called by muse, mutect2, varscan2
- PTPRN | c.1393C>T p.R465C | Missense Mutation (SNP) | VAF 120/315 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as rs760369284, COSV99834502; called by muse, mutect2, varscan2
- RASAL3 | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 92/345 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as rs756715519, COSV59138328; called by muse, mutect2, varscan2
- RET | c.1387G>A p.G463R | Missense Mutation (SNP) | VAF 115/475 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as CM1211882, COSV60687224; called by muse, varscan2
- RIMBP2 | c.2929G>A p.E977K | Missense Mutation (SNP) | VAF 53/223 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1056369202, COSV55484365; called by muse, mutect2, varscan2
- RP1L1 | c.6091G>A p.G2031S | Missense Mutation (SNP) | VAF 184/497 reads (37%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.003); catalogued as rs1235044813; called by muse, mutect2, varscan2
- SEC24A | c.2455C>T p.R819C | Missense Mutation (SNP) | VAF 86/296 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs925687618, COSV63274843, COSV63274943; called by muse, mutect2, varscan2
- SLC17A8 | c.416G>A p.G139D | Missense Mutation (SNP) | VAF 72/259 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1377420426; called by muse, mutect2, varscan2
- SLC24A4 | c.1682C>T p.S561F | Missense Mutation (SNP) | VAF 112/223 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1472393642, COSV54108219; called by muse, mutect2, varscan2
- SLIT3 | c.2282G>A p.G761E | Missense Mutation (SNP) | VAF 80/324 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1254306549, COSV60613685; called by muse, mutect2, varscan2
- SNTG1 | c.1372G>A p.D458N | Missense Mutation (SNP) | VAF 30/193 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.321); catalogued as rs779331784; called by muse, mutect2, varscan2
- SOX17 | c.845C>T p.S282L | Missense Mutation (SNP) | VAF 71/421 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs1219111000, COSV52024315; called by muse, mutect2, varscan2
- SPEG | c.1573C>T p.P525S | Missense Mutation (SNP) | VAF 88/444 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as rs1048630657; called by muse, mutect2, varscan2
- SPSB1 | c.164C>T p.S55L | Missense Mutation (SNP) | VAF 143/468 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV60163770; called by muse, mutect2, varscan2
- SYCP1 | c.1666G>A p.E556K | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV65697666, COSV65700949; called by muse, mutect2, varscan2
- TAS2R60 | c.639G>A p.M213I | Missense Mutation (SNP) | VAF 127/349 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.018); catalogued as rs141559059, COSV60330146; called by muse, mutect2, varscan2
- TBC1D22A | c.1381C>T p.L461F | Missense Mutation (SNP) | VAF 125/372 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100453227; called by muse, mutect2, varscan2
- THSD7B | c.968C>T p.S323F | Missense Mutation (SNP) | VAF 57/172 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.851); catalogued as rs267598895, COSV55707231; called by muse, mutect2, varscan2
- TIMM44 | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 119/406 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as rs780589464, COSV54491149, COSV99564172; called by muse, mutect2, varscan2
- TJP1 | c.2824A>G p.T942A | Missense Mutation (SNP) | VAF 136/395 reads (34%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs1394794254; called by muse, mutect2, varscan2
- TMC5 | c.1912T>G p.Y638D (on ENST00000396229 / NM_001105248.1; = p.Y392D on NM_024780.5) | Missense Mutation (SNP) | VAF 85/290 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs893608125; called by muse, mutect2, varscan2
- TMEM72 | c.316C>T p.H106Y | Missense Mutation (SNP) | VAF 62/419 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs772674668; called by muse, mutect2, varscan2
- TNR | c.2809C>T p.R937W | Missense Mutation (SNP) | VAF 237/386 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs150401432, COSV54882302; called by muse, mutect2, varscan2
- TPRX1 | c.988C>T p.P330S | Missense Mutation (SNP) | VAF 67/459 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as rs763057221, COSV59115147; called by muse, mutect2, varscan2
- TRBV23-1 | c.13C>T p.L5F | Missense Mutation (SNP) | VAF 112/276 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.863); catalogued as rs1424434683; called by muse, mutect2, varscan2
- TTN | c.59110G>A p.E19704K (on ENST00000591111; = p.E12280K on NM_003319.4) | Missense Mutation (SNP) | VAF 124/352 reads (35%) | PolyPhen benign (0.05); catalogued as rs776495338, COSV60242480; called by muse, mutect2, varscan2
- TTN | c.16082G>A p.R5361Q (on ENST00000591111; = p.R4434Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/397 reads (13%) | PolyPhen possibly damaging (0.75); catalogued as rs374742663, COSV60318230; called by muse, mutect2, varscan2
- UMODL1 | c.3032C>T p.S1011F (on ENST00000408910 / NM_001004416.2; = p.S1139F on NM_173568.3) | Missense Mutation (SNP) | VAF 130/453 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as rs267606137; called by muse, mutect2, varscan2
- VSIG10L | c.707G>A p.G236E | Missense Mutation (SNP) | VAF 203/597 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1446363558; called by muse, mutect2, varscan2
- VWA3B | c.3323G>A p.G1108E | Missense Mutation (SNP) | VAF 104/380 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.831); catalogued as rs755901737; called by muse, mutect2, varscan2
- ZFYVE26 | c.946C>T p.P316S | Missense Mutation (SNP) | VAF 125/246 reads (51%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as COSV100720127; called by muse, mutect2, varscan2
- ZNF285 | c.1090G>A p.G364R | Missense Mutation (SNP) | VAF 105/360 reads (29%) | SIFT tolerated (0.92); PolyPhen possibly damaging (0.75); catalogued as rs1184690393; called by muse, mutect2, varscan2
- ZNF485 | c.1246G>A p.G416R | Missense Mutation (SNP) | VAF 115/343 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as COSV62424876; called by muse, mutect2, varscan2
- ZNF616 | c.2215C>T p.H739Y | Missense Mutation (SNP) | VAF 49/351 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs371337850, COSV57509574; called by muse, mutect2, varscan2
- ZNF696 | c.439C>T p.H147Y | Missense Mutation (SNP) | VAF 197/679 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as rs1486318641; called by muse, mutect2, varscan2
- ZNF727 | c.995G>A p.R332K | Missense Mutation (SNP) | VAF 56/270 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.043); catalogued as COSV70702445; called by muse, mutect2, varscan2
- AC091167.6 | c.274A>T p.R92W | Missense Mutation (SNP) | VAF 72/209 reads (34%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- ADAM19 | c.2675C>T p.S892F | Missense Mutation (SNP) | VAF 62/485 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ADGRL3 | c.4208A>G p.N1403S (on ENST00000506720 / NM_001322402.2; = p.N1292S on NM_015236.6) | Missense Mutation (SNP) | VAF 125/450 reads (28%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ANK3 | c.5783C>T p.P1928L | Missense Mutation (SNP) | VAF 66/414 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ARHGAP27 | c.2449C>T p.P817S (on ENST00000428638 / NM_001282290.1; = p.P476S on NM_199282.3) | Missense Mutation (SNP) | VAF 153/454 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARMH2 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 94/295 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- BANP | c.1379C>T p.S460F (on ENST00000286122; = p.S410F on NM_017869.4) | Missense Mutation (SNP) | VAF 169/503 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- BIRC6 | c.12784C>T p.P4262S | Missense Mutation (SNP) | VAF 107/277 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- BLNK | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 92/321 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- C10orf71 | c.2275G>A p.D759N | Missense Mutation (SNP) | VAF 121/407 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C2CD3 | c.1531G>C p.E511Q | Missense Mutation (SNP) | VAF 39/204 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- C2orf16 | c.3604G>A p.D1202N | Missense Mutation (SNP) | VAF 76/269 reads (28%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CADPS2 | c.945G>C p.L315F | Missense Mutation (SNP) | VAF 42/261 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CD1C | c.174G>A p.W58* | Nonsense Mutation (SNP) | VAF 323/478 reads (68%) | called by muse, mutect2, varscan2
- CILP2 | c.2324C>T p.P775L | Missense Mutation (SNP) | VAF 185/605 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CLDN16 | c.575-1G>A p.X192_splice | Splice Site (SNP) | VAF 76/214 reads (36%) | called by muse, mutect2, varscan2
- CNTNAP4 | c.1118C>T p.T373I | Missense Mutation (SNP) | VAF 112/349 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL6A5 | c.5918A>G p.N1973S (on ENST00000312481; = p.N1969S on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 101/335 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- COPB2 | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 98/319 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- COQ7 | c.556C>T p.L186F | Missense Mutation (SNP) | VAF 97/344 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CREB5 | c.949C>A p.H317N (on ENST00000357727 / NM_182898.4; = p.H310N on NM_004904.3) | Missense Mutation (SNP) | VAF 87/841 reads (10%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- CSF1R | c.1497A>G p.I499M | Missense Mutation (SNP) | VAF 67/219 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- CSMD1 | c.9490G>A p.E3164K (on ENST00000520002; = p.E3163K on NM_033225.6) | Missense Mutation (SNP) | VAF 34/213 reads (16%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CYB561 | c.379C>A p.L127I | Missense Mutation (SNP) | VAF 113/483 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CYP4F2 | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 116/363 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CYP4V2 | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 104/391 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CYP4V2 | c.1256C>T p.A419V | Missense Mutation (SNP) | VAF 107/328 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DCHS2 | c.1163G>A p.G388E | Missense Mutation (SNP) | VAF 108/408 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- DDX25 | c.409C>A p.Q137K | Missense Mutation (SNP) | VAF 63/181 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- DEFB115 | c.92C>A p.P31Q | Missense Mutation (SNP) | VAF 47/251 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- DIDO1 | c.5245C>T p.P1749S | Missense Mutation (SNP) | VAF 166/529 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DISP3 | c.1507C>T p.L503F | Missense Mutation (SNP) | VAF 47/415 reads (11%) | SIFT tolerated (0.2); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DLEC1 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 119/438 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- DNM1L | c.1284_1285del p.L429Pfs*8 | Frame Shift Del (DEL) | VAF 125/446 reads (28%) | called by mutect2, pindel*, varscan2*
- ECHDC2 | c.860C>T p.P287L (on ENST00000371522 / NM_001198961.2; = p.P256L on NM_018281.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 95/302 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EFCAB8 | c.3241C>T p.P1081S | Missense Mutation (SNP) | VAF 113/346 reads (33%) | SIFT tolerated (0.97); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EIF2AK4 | c.631C>T p.H211Y | Missense Mutation (SNP) | VAF 97/272 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- EMX2 | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 106/310 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ERICH3 | c.3366G>A p.M1122I | Missense Mutation (SNP) | VAF 143/444 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- ERVMER34-1 | c.1267G>A p.D423N | Missense Mutation (SNP) | VAF 113/330 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FAM83B | c.609G>A p.R203= | Splice Region (SNP) | VAF 49/175 reads (28%) | called by muse, mutect2, varscan2
- FGD6 | c.3615T>A p.N1205K | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FHL3 | c.293C>T p.S98F | Missense Mutation (SNP) | VAF 113/376 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FLT4 | c.3296C>T p.S1099F | Missense Mutation (SNP) | VAF 117/368 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FRMPD2 | c.570G>A p.V190= | Splice Region (SNP) | VAF 75/233 reads (32%) | called by muse, mutect2, varscan2
- GPC6 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 304/555 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- GPR26 | c.136C>A p.L46M | Missense Mutation (SNP) | VAF 66/493 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- HERPUD2 | c.148T>G p.L50V | Missense Mutation (SNP) | VAF 217/386 reads (56%) | SIFT tolerated (0.52); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- HTRA1 | c.760A>T p.I254F | Missense Mutation (SNP) | VAF 51/258 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- IGDCC3 | c.2289G>C p.K763N | Missense Mutation (SNP) | VAF 169/549 reads (31%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IRS2 | c.894C>G p.F298L | Missense Mutation (SNP) | VAF 128/653 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- ITGA2 | c.2867A>G p.N956S | Missense Mutation (SNP) | VAF 82/304 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ITPKA | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 77/243 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITPR1 | c.3705G>A p.M1235I (on ENST00000354582; = p.M1220I on NM_002222.7) | Missense Mutation (SNP) | VAF 106/352 reads (30%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- KCNA5 | c.1787T>C p.L596S | Missense Mutation (SNP) | VAF 62/343 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.69); called by muse, varscan2
- KCNA7 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 178/545 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNB2 | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 143/348 reads (41%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- KLHDC8B | c.112G>A p.G38S | Missense Mutation (SNP) | VAF 191/570 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLKB1 | c.1112C>T p.S371F | Missense Mutation (SNP) | VAF 90/286 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KRTAP10-6 | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 69/261 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LOXHD1 | c.3022G>T p.V1008F | Missense Mutation (SNP) | VAF 72/224 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- LRP3 | c.1810C>T p.L604F | Missense Mutation (SNP) | VAF 183/618 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- LRP4 | c.1871G>A p.R624K | Missense Mutation (SNP) | VAF 98/215 reads (46%) | SIFT tolerated (0.77); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- LRRC58 | c.565C>T p.P189S | Missense Mutation (SNP) | VAF 50/269 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- MACC1 | c.2038G>A p.D680N | Missense Mutation (SNP) | VAF 100/379 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- MAP1A | c.6976G>A p.G2326R | Missense Mutation (SNP) | VAF 140/462 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MAPRE2 | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 71/266 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- MCRS1 | c.1013C>T p.S338F | Missense Mutation (SNP) | VAF 85/302 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- MORC1 | c.1196G>A p.G399E | Missense Mutation (SNP) | VAF 63/226 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- MUC16 | c.37992G>A p.W12664* | Nonsense Mutation (SNP) | VAF 91/275 reads (33%) | called by muse, mutect2, varscan2
- MYOF | c.4414C>T p.Q1472* | Nonsense Mutation (SNP) | VAF 75/271 reads (28%) | called by muse, mutect2, varscan2
- NECTIN4 | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 192/324 reads (59%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NEXMIF | c.137C>A p.P46H | Missense Mutation (SNP) | VAF 117/194 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- NFE2 | c.874G>A p.V292M | Missense Mutation (SNP) | VAF 61/503 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- NLRP13 | c.1284T>G p.C428W | Missense Mutation (SNP) | VAF 124/407 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPRL3 | c.1262C>T p.P421L (on ENST00000611875 / NM_001077350.3; = p.P396L on NM_001039476.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 128/440 reads (29%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, varscan2
- OLAH | c.471G>A p.M157I (on ENST00000378228 / NM_001039702.3; = p.M210I on NM_018324.3) | Missense Mutation (SNP) | VAF 152/315 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- OLFM4 | c.1211A>G p.N404S | Missense Mutation (SNP) | VAF 101/380 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OR4K3 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 107/377 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHB12 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 102/360 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PDCD4 | c.317C>T p.S106F | Missense Mutation (SNP) | VAF 73/248 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- PHEX | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 154/236 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- PLCH1 | c.700G>A p.E234K (on ENST00000340059 / NM_001130960.2; = p.E246K on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/261 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- PLEKHM3 | c.1814G>A p.R605Q | Missense Mutation (SNP) | VAF 149/388 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- POLR3A | c.1183A>T p.K395* | Nonsense Mutation (SNP) | VAF 74/248 reads (30%) | called by muse, mutect2, varscan2
- POM121L12 | c.730A>C p.S244R | Missense Mutation (SNP) | VAF 373/707 reads (53%) | SIFT tolerated (0.05); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PPP4R1 | c.322G>A p.E108K (on ENST00000400556 / NM_001042388.3; = p.E91K on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 99/327 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PRAMEF17 | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 61/460 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PSG6 | c.700C>G p.L234V | Missense Mutation (SNP) | VAF 50/302 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- RAB3GAP1 | c.1201C>T p.P401S | Missense Mutation (SNP) | VAF 31/187 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- RAPGEF5 | c.436A>G p.K146E (on ENST00000401957 / NM_001367602.2; = p.K449E on NM_012294.5) | Missense Mutation (SNP) | VAF 131/544 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- RASGRP1 | c.1459G>A p.D487N | Missense Mutation (SNP) | VAF 35/240 reads (15%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- RGPD4 | c.2620C>G p.P874A | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- RIMS2 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 129/479 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNF40 | c.754C>T p.H252Y | Missense Mutation (SNP) | VAF 90/292 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- RP1 | c.4114G>A p.E1372K | Missense Mutation (SNP) | VAF 112/278 reads (40%) | SIFT tolerated (0.68); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- SCN7A | c.635G>A p.R212K | Missense Mutation (SNP) | VAF 33/183 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- SCN9A | c.2520C>T p.L840= (on ENST00000303354; = p.L829= on NM_002977.3) | Splice Region (SNP) | VAF 34/209 reads (16%) | called by muse, mutect2, varscan2
- SERPINB4 | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 129/412 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- SGK2 | c.614G>A p.S205N | Missense Mutation (SNP) | VAF 50/379 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- SIGLEC14 | c.982C>A p.Q328K | Missense Mutation (SNP) | VAF 56/376 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- SLC12A7 | c.2749G>A p.D917N | Missense Mutation (SNP) | VAF 76/205 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- SLC25A18 | c.914G>A p.G305E | Missense Mutation (SNP) | VAF 57/322 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SLC4A2 | c.2165C>T p.P722L | Missense Mutation (SNP) | VAF 48/284 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SLC7A1 | c.241G>A p.G81S | Missense Mutation (SNP) | VAF 109/385 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLITRK6 | c.1202T>C p.V401A | Missense Mutation (SNP) | VAF 137/379 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- SPATA31E1 | c.2368C>T p.L790F | Missense Mutation (SNP) | VAF 189/333 reads (57%) | SIFT tolerated (0.33); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- SPEG | c.1574C>T p.P525L | Missense Mutation (SNP) | VAF 89/448 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SYNRG | c.871C>T p.P291S | Missense Mutation (SNP) | VAF 43/331 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- SYT15 | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 58/445 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- TLK1 | c.1252C>T p.Q418* | Nonsense Mutation (SNP) | VAF 101/263 reads (38%) | called by muse, mutect2, varscan2
- TMEM132B | c.1160G>T p.G387V | Missense Mutation (SNP) | VAF 100/355 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- TMTC1 | c.1356G>T p.L452F (on ENST00000539277 / NM_001193451.2; = p.L344F on NM_175861.3) | Missense Mutation (SNP) | VAF 148/418 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRIM64B | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 130/737 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- TTI1 | c.2594A>T p.D865V | Missense Mutation (SNP) | VAF 127/431 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- TTN | c.79304G>A p.W26435* (on ENST00000591111; = p.W19011* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 40/276 reads (14%) | called by muse, mutect2, varscan2
- TTN | c.21116G>A p.W7039* (on ENST00000591111; = p.W6112* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 54/313 reads (17%) | called by muse, mutect2, varscan2
- UBR4 | c.4603C>T p.P1535S | Missense Mutation (SNP) | VAF 185/461 reads (40%) | SIFT tolerated (0.83); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- UGDH | c.838G>A p.D280N | Missense Mutation (SNP) | VAF 100/280 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UMODL1 | c.3757C>T p.P1253S (on ENST00000408910 / NM_001004416.2; = p.P1381S on NM_173568.3) | Missense Mutation (SNP) | VAF 89/344 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- WASF3 | c.1502C>T p.S501F | Missense Mutation (SNP) | VAF 52/201 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- WDR87 | c.373C>T p.L125F | Missense Mutation (SNP) | VAF 130/415 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZBTB48 | c.824C>G p.S275C | Missense Mutation (SNP) | VAF 124/342 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZC3H8 | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 36/319 reads (11%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF469 | c.1726C>T p.P576S | Missense Mutation (SNP) | VAF 81/547 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- ZSCAN5B | c.718C>G p.P240A | Missense Mutation (SNP) | VAF 34/308 reads (11%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ABCC4 | c.1068G>A p.T356= | Silent (SNP) | VAF 115/495 reads (23%) | catalogued as rs374882007, COSV100972577, COSV65311157; called by muse, mutect2, varscan2
- ACTN1 | c.693C>T p.A231= | Silent (SNP) | VAF 53/125 reads (42%) | catalogued as COSV99517261; called by muse, mutect2, varscan2
- ADAM11 | c.435C>T p.S145= | Silent (SNP) | VAF 110/419 reads (26%) | called by muse, mutect2, varscan2
- ADAM28 | c.1956C>T p.I652= | Silent (SNP) | VAF 39/261 reads (15%) | catalogued as rs777423480, COSV56097541; called by muse, mutect2, varscan2
- AGXT | c.384G>A p.K128= | Silent (SNP) | VAF 45/261 reads (17%) | catalogued as rs1278094631; called by muse, mutect2, varscan2
- AMPD2 | c.1290C>T p.F430= | Silent (SNP) | VAF 85/274 reads (31%) | called by muse, mutect2, varscan2
- ANK3 | c.4941C>A p.P1647= | Silent (SNP) | VAF 47/382 reads (12%) | called by muse, mutect2, varscan2
- ANK3 | c.1911C>T p.I637= | Silent (SNP) | VAF 78/257 reads (30%) | catalogued as rs539885495, COSV55078786; called by muse, mutect2, varscan2
- ATP8B2 | c.1221C>T p.A407= (on ENST00000672630; = p.A374= on NM_001367934.1 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 338/499 reads (68%) | called by muse, mutect2, varscan2
- BRINP2 | c.261G>A p.R87= | Silent (SNP) | VAF 169/250 reads (68%) | catalogued as COSV64175415; called by muse, mutect2, varscan2
- BRSK1 | c.2094C>T p.P698= | Silent (SNP) | VAF 71/250 reads (28%) | called by muse, mutect2, varscan2
- CA10 | c.408G>A p.G136= | Silent (SNP) | VAF 120/428 reads (28%) | catalogued as rs758370242; called by muse, mutect2, varscan2
- CCDC9 | c.594C>T p.P198= | Silent (SNP) | VAF 169/572 reads (30%) | catalogued as rs776255827, COSV55719924; called by muse, mutect2
- CEP250 | c.6897C>T p.T2299= | Silent (SNP) | VAF 66/271 reads (24%) | catalogued as COSV61170329, COSV61172610; called by muse, mutect2, varscan2
- CEP295 | c.7692G>A p.V2564= | Silent (SNP) | VAF 47/149 reads (32%) | catalogued as rs774408569; called by muse, mutect2, varscan2
- CFAP58 | c.1773G>A p.E591= | Silent (SNP) | VAF 87/330 reads (26%) | called by muse, mutect2, varscan2
- CFH | c.3009G>A p.E1003= | Silent (SNP) | VAF 56/418 reads (13%) | catalogued as rs111924608; called by muse, mutect2, varscan2
- CFHR3 | c.21C>T p.V7= | Silent (SNP) | VAF 216/327 reads (66%) | called by muse, mutect2, varscan2
- CILP2 | c.2325C>T p.P775= | Silent (SNP) | VAF 180/603 reads (30%) | called by muse, mutect2, varscan2
- COL13A1 | c.1041G>A p.G347= (on ENST00000398978 / NM_001130103.2; = p.G290= on NM_080798.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 102/341 reads (30%) | catalogued as COSV100637421; called by muse, mutect2, varscan2
- COPG1 | c.2352G>A p.E784= | Silent (SNP) | VAF 86/358 reads (24%) | catalogued as rs1560068895; called by muse, mutect2, varscan2
- CSMD1 | c.2532C>T p.F844= (on ENST00000520002; = p.F843= on NM_033225.6) | Silent (SNP) | VAF 52/374 reads (14%) | catalogued as rs1268070924, COSV59283424; called by muse, mutect2
- CYB561 | c.273C>T p.H91= | Silent (SNP) | VAF 96/443 reads (22%) | called by muse, mutect2, varscan2
- DIP2B | c.2514A>C p.I838= | Silent (SNP) | VAF 62/187 reads (33%) | called by muse, mutect2, varscan2
- DIRAS2 | c.360G>A p.G120= | Silent (SNP) | VAF 77/320 reads (24%) | catalogued as rs781363488; called by muse, mutect2, varscan2
- DLEC1 | c.5178G>A p.V1726= | Silent (SNP) | VAF 94/327 reads (29%) | catalogued as rs543937258, COSV100085951; called by muse, mutect2, varscan2
- DNAH11 | c.243G>A p.L81= | Silent (SNP) | VAF 329/768 reads (43%) | called by muse, varscan2
- DPF2 | c.693C>T p.S231= | Silent (SNP) | VAF 65/354 reads (18%) | catalogued as COSV52890145; called by muse, mutect2, varscan2
- DPP6 | c.2514C>T p.S838= (on ENST00000377770 / NM_001364500.2; = p.S776= on NM_001936.5) | Silent (SNP) | VAF 63/353 reads (18%) | called by muse, mutect2, varscan2
- DSCAM | c.3870C>T p.T1290= | Silent (SNP) | VAF 63/276 reads (23%) | catalogued as rs907099949, COSV68022906; called by muse, mutect2, varscan2
- DUXA | c.414C>T p.I138= | Silent (SNP) | VAF 68/235 reads (29%) | catalogued as rs267605726, COSV73729839; called by muse, varscan2
- DZIP1L | c.843C>T p.V281= | Silent (SNP) | VAF 42/165 reads (25%) | catalogued as rs747418381, COSV59519841, COSV59520261; called by muse, mutect2, varscan2
- E4F1 | c.1860C>T p.V620= | Silent (SNP) | VAF 178/540 reads (33%) | catalogued as rs1450935873; called by muse, mutect2, varscan2
- EFHC2 | c.834C>T p.F278= | Silent (SNP) | VAF 89/158 reads (56%) | catalogued as rs760709274, COSV69552720; called by muse, mutect2, varscan2
- ERG | c.399C>T p.I133= | Silent (SNP) | VAF 89/293 reads (30%) | catalogued as rs1473346716, COSV55727171; called by muse, mutect2, varscan2
- ERVMER34-1 | c.168C>A p.P56= | Silent (SNP) | VAF 40/302 reads (13%) | catalogued as rs766595866; called by muse, mutect2, varscan2
- EVPL | c.3078C>T p.P1026= | Silent (SNP) | VAF 74/624 reads (12%) | catalogued as rs371295003, COSV56907142; called by muse, mutect2, varscan2
- FARSA | c.618C>T p.P206= | Silent (SNP) | VAF 98/311 reads (32%) | catalogued as rs11538254; called by muse, mutect2, varscan2
- FBXO21 | c.916C>T p.L306= | Silent (SNP) | VAF 101/336 reads (30%) | called by muse, mutect2, varscan2
- FOXE1 | c.333C>T p.F111= | Silent (SNP) | VAF 87/403 reads (22%) | called by muse, mutect2, varscan2
- FREM3 | c.6372G>A p.E2124= | Silent (SNP) | VAF 129/465 reads (28%) | called by muse, mutect2, varscan2
- FRMPD2 | c.39C>T p.S13= | Silent (SNP) | VAF 87/310 reads (28%) | catalogued as COSV59723742; called by muse, mutect2, varscan2
- GABRE | c.804G>A p.T268= | Silent (SNP) | VAF 124/192 reads (65%) | called by muse, mutect2, varscan2
- GNB1 | c.300C>T p.V100= | Silent (SNP) | VAF 111/331 reads (34%) | called by muse, mutect2, varscan2
- GPR89A | c.27C>T p.I9= | Silent (SNP) | VAF 135/352 reads (38%) | called by muse, mutect2, varscan2
- GREB1 | c.420C>T p.F140= | Silent (SNP) | VAF 144/418 reads (34%) | called by muse, mutect2, varscan2
- GUCY1B1 | c.1653C>T p.S551= | Silent (SNP) | VAF 66/424 reads (16%) | called by muse, mutect2, varscan2
- HLA-C | c.879C>T p.P293= | Silent (SNP) | VAF 138/442 reads (31%) | catalogued as rs779607111; called by muse, mutect2, varscan2
- HMOX1 | c.222C>T p.F74= | Silent (SNP) | VAF 206/552 reads (37%) | catalogued as rs148073049; ClinVar: likely benign; called by muse, mutect2, varscan2
- HPX | c.15G>T p.L5= | Silent (SNP) | VAF 60/325 reads (18%) | called by muse, mutect2, varscan2
- INHBE | c.696G>A p.R232= | Silent (SNP) | VAF 193/538 reads (36%) | catalogued as COSV56988404, COSV56989240; called by muse, mutect2, varscan2
- ITGB5 | c.1002C>T p.I334= | Silent (SNP) | VAF 122/383 reads (32%) | catalogued as COSV56150244; called by muse, mutect2, varscan2
- ITPRID2 | c.1245C>T p.S415= | Silent (SNP) | VAF 86/237 reads (36%) | called by muse, mutect2, varscan2
- KCNA5 | c.435C>T p.L145= | Silent (SNP) | VAF 153/511 reads (30%) | called by muse, varscan2
- KCNA5 | c.436C>T p.L146= | Silent (SNP) | VAF 162/539 reads (30%) | called by muse, mutect2, varscan2
- KCNB2 | c.2184G>A p.Q728= | Silent (SNP) | VAF 129/346 reads (37%) | catalogued as COSV101578843, COSV73050385; called by muse, mutect2, varscan2
- KCNK5 | c.1269G>A p.V423= | Silent (SNP) | VAF 117/490 reads (24%) | called by muse, mutect2, varscan2
- KCNMB2 | c.255C>T p.T85= | Silent (SNP) | VAF 110/308 reads (36%) | called by muse, mutect2, varscan2
- KCNQ2 | c.300C>T p.F100= | Silent (SNP) | VAF 104/378 reads (28%) | catalogued as rs1432645663; called by muse, mutect2, varscan2
- KIR2DL1 | c.945C>T p.I315= | Silent (SNP) | VAF 165/543 reads (30%) | called by muse, mutect2, varscan2
- KLF12 | c.450C>T p.A150= | Silent (SNP) | VAF 149/419 reads (36%) | called by muse, mutect2, varscan2
- KLF4 | c.843G>A p.A281= | Silent (SNP) | VAF 62/368 reads (17%) | catalogued as rs945840739, COSV65929384; called by muse, varscan2
- KMT2D | c.3675C>T p.P1225= | Silent (SNP) | VAF 131/425 reads (31%) | catalogued as COSV99981307; called by muse, mutect2, varscan2
- LAMB3 | c.3288C>T p.S1096= | Silent (SNP) | VAF 375/565 reads (66%) | called by muse, mutect2, varscan2
- LINGO1 | c.1836C>T p.P612= | Silent (SNP) | VAF 75/199 reads (38%) | called by muse, mutect2, varscan2
- LRFN1 | c.883C>T p.L295= | Silent (SNP) | VAF 195/549 reads (36%) | called by muse, mutect2, varscan2
- LRP8 | c.2304C>T p.S768= | Silent (SNP) | VAF 144/467 reads (31%) | called by muse, mutect2, varscan2
- MARCOL | c.366C>T p.N122= | Silent (SNP) | VAF 81/268 reads (30%) | called by muse, mutect2, varscan2
- ME1 | c.1335G>A p.Q445= | Silent (SNP) | VAF 66/263 reads (25%) | called by muse, mutect2, varscan2
- MRFAP1 | c.282C>T p.A94= | Silent (SNP) | VAF 153/537 reads (28%) | called by muse, mutect2, varscan2
- MRRF | c.201G>A p.Q67= | Silent (SNP) | VAF 72/179 reads (40%) | catalogued as rs775916306; called by muse, mutect2, varscan2
- MS4A15 | c.591C>T p.A197= (on ENST00000405633 / NM_001098835.2; = p.A104= on NM_152717.3) | Silent (SNP) | VAF 69/209 reads (33%) | catalogued as rs1473209709; called by muse, mutect2, varscan2
- MTOR | c.2988G>A p.T996= | Silent (SNP) | VAF 60/365 reads (16%) | catalogued as rs200775211; called by muse, mutect2
- MYEF2 | c.228G>A p.K76= | Silent (SNP) | VAF 48/273 reads (18%) | called by muse, mutect2, varscan2
- MYH1 | c.4647G>A p.E1549= | Silent (SNP) | VAF 68/149 reads (46%) | catalogued as rs376217197; called by muse, mutect2, varscan2
- NBEAL2 | c.4494G>A p.E1498= | Silent (SNP) | VAF 70/289 reads (24%) | called by muse, mutect2, varscan2
- NDST4 | c.765G>A p.T255= | Silent (SNP) | VAF 95/364 reads (26%) | catalogued as rs373574580; called by muse, mutect2, varscan2
- NPAP1 | c.567C>T p.S189= | Silent (SNP) | VAF 108/387 reads (28%) | called by muse, mutect2, varscan2
- NR1H4 | c.387G>A p.G129= (on ENST00000551379 / NM_001206993.2; = p.G119= on NM_005123.4) | Silent (SNP) | VAF 69/449 reads (15%) | catalogued as rs753912475, COSV51851689; called by muse, mutect2, varscan2
- ONECUT2 | c.1434G>A p.R478= | Silent (SNP) | VAF 130/402 reads (32%) | called by muse, mutect2, varscan2
- OR4A8 | c.591G>A p.V197= | Silent (SNP) | VAF 27/212 reads (13%) | called by muse, mutect2, varscan2
- OR4C6 | c.399C>T p.I133= | Silent (SNP) | VAF 115/334 reads (34%) | catalogued as COSV58602546; called by muse, mutect2, varscan2
- OR5R1 | c.237G>A p.P79= | Silent (SNP) | VAF 53/262 reads (20%) | catalogued as rs143277109; called by muse, mutect2, varscan2
- PCDHGB1 | c.2079C>T p.A693= | Silent (SNP) | VAF 54/401 reads (13%) | called by muse, mutect2, varscan2
- PI3 | c.342C>T p.F114= | Silent (SNP) | VAF 37/275 reads (13%) | catalogued as rs371430509; called by muse, mutect2, varscan2
- POLR3A | c.3813C>T p.I1271= | Silent (SNP) | VAF 89/336 reads (26%) | called by muse, mutect2, varscan2
- POU2F2 | c.933C>T p.A311= (on ENST00000526816 / NM_001207025.3; = p.A295= on NM_002698.5) | Silent (SNP) | VAF 67/261 reads (26%) | called by muse, mutect2, varscan2
- RASAL3 | c.480C>T p.P160= | Silent (SNP) | VAF 84/318 reads (26%) | called by muse, varscan2
- RP1 | c.4275A>C p.L1425= | Silent (SNP) | VAF 37/209 reads (18%) | called by muse, mutect2, varscan2
- SALL3 | c.1521G>A p.K507= | Silent (SNP) | VAF 104/628 reads (17%) | catalogued as rs753790358; called by muse, varscan2
- SALL4 | c.3003C>T p.S1001= | Silent (SNP) | VAF 150/488 reads (31%) | called by muse, mutect2, varscan2
- SCN4A | c.534C>T p.A178= | Silent (SNP) | VAF 213/454 reads (47%) | catalogued as COSV71128058; called by muse, mutect2, varscan2
- SCRIB | c.4668C>T p.P1556= | Silent (SNP) | VAF 70/498 reads (14%) | catalogued as rs552260202; called by muse, varscan2
- SIPA1L3 | c.1830A>G p.Q610= | Silent (SNP) | VAF 90/288 reads (31%) | called by muse, mutect2, varscan2
- SLC2A1 | c.534C>T p.S178= | Silent (SNP) | VAF 96/315 reads (30%) | called by muse, mutect2, varscan2
- SLC35F3 | c.1155G>A p.L385= (on ENST00000366617 / NM_001300845.1; = p.L454= on NM_173508.4) | Silent (SNP) | VAF 295/461 reads (64%) | catalogued as rs1360196552; called by muse, mutect2, varscan2
- SLC37A3 | c.996C>T p.S332= | Silent (SNP) | VAF 72/234 reads (31%) | catalogued as rs749047184; called by muse, mutect2, varscan2
- SLC9A4 | c.846C>T p.I282= | Silent (SNP) | VAF 142/442 reads (32%) | catalogued as rs759238987, COSV54834011, COSV99763034; called by muse, mutect2, varscan2
- SLIT3 | c.354G>A p.K118= | Silent (SNP) | VAF 85/285 reads (30%) | called by muse, mutect2, varscan2
- SLITRK1 | c.1329C>T p.F443= | Silent (SNP) | VAF 110/427 reads (26%) | catalogued as COSV65675068; called by muse, mutect2, varscan2
- SNAPC4 | c.2217C>T p.L739= | Silent (SNP) | VAF 279/483 reads (58%) | called by muse, mutect2, varscan2
- SORCS3 | c.3156C>T p.L1052= | Silent (SNP) | VAF 47/334 reads (14%) | catalogued as rs775223969, COSV63804417; called by muse, mutect2, varscan2
- SOX9 | c.1392C>T p.S464= | Silent (SNP) | VAF 86/564 reads (15%) | catalogued as COSV55429444; called by muse, mutect2, varscan2
- SPRR2A | c.30G>A p.Q10= | Silent (SNP) | VAF 60/314 reads (19%) | called by muse, mutect2, varscan2
- SRMS | c.1242C>T p.V414= | Silent (SNP) | VAF 62/410 reads (15%) | catalogued as rs758668728; called by muse, mutect2, varscan2
- STAB2 | c.3273C>T p.F1091= | Silent (SNP) | VAF 84/249 reads (34%) | catalogued as rs751626024, COSV66333499; called by muse, mutect2, varscan2
- STEAP3 | c.477G>A p.R159= | Silent (SNP) | VAF 72/290 reads (25%) | catalogued as COSV61531457; called by muse, mutect2, varscan2
- STRIP1 | c.1191C>T p.P397= | Silent (SNP) | VAF 122/438 reads (28%) | catalogued as COSV63930168; called by muse, mutect2, varscan2
- TANC1 | c.51G>A p.K17= | Silent (SNP) | VAF 49/270 reads (18%) | called by muse, mutect2, varscan2
- TEX44 | c.474C>T p.S158= | Silent (SNP) | VAF 156/395 reads (39%) | called by muse, mutect2, varscan2
- TIAM1 | c.1311C>A p.A437= | Silent (SNP) | VAF 156/511 reads (31%) | called by muse, mutect2, varscan2
- TIMM44 | c.822G>A p.R274= | Silent (SNP) | VAF 119/409 reads (29%) | called by muse, mutect2, varscan2
- TMOD3 | c.696C>T p.F232= | Silent (SNP) | VAF 120/370 reads (32%) | catalogued as COSV100419190; called by muse, mutect2, varscan2
- TTC1 | c.108C>T p.P36= | Silent (SNP) | VAF 94/401 reads (23%) | catalogued as COSV51464516; called by muse, mutect2, varscan2
- TTI1 | c.2595C>T p.D865= | Silent (SNP) | VAF 128/434 reads (29%) | catalogued as rs1193813915, COSV100989595; called by muse, mutect2, varscan2
- TTN | c.25914C>T p.I8638= (on ENST00000591111; = p.I7711= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 48/351 reads (14%) | called by muse, mutect2, varscan2
- UPK1A | c.171G>A p.K57= | Silent (SNP) | VAF 69/468 reads (15%) | called by muse, mutect2, varscan2
- USP17L2 | c.96C>T p.I32= | Silent (SNP) | VAF 127/716 reads (18%) | called by muse, mutect2, varscan2
- USP22 | c.1281C>T p.S427= | Silent (SNP) | VAF 110/345 reads (32%) | called by muse, mutect2, varscan2
- VPS13D | c.2652C>T p.I884= | Silent (SNP) | VAF 84/247 reads (34%) | catalogued as rs776304147, COSV99165315; called by muse, mutect2, varscan2
- XKR7 | c.1293C>T p.F431= | Silent (SNP) | VAF 132/399 reads (33%) | catalogued as COSV73813240; called by muse, mutect2, varscan2
- ZFHX3 | c.2859C>T p.F953= | Silent (SNP) | VAF 72/442 reads (16%) | called by muse, mutect2, varscan2
- ZNF404 | c.147C>T p.F49= | Silent (SNP) | VAF 27/147 reads (18%) | called by muse, mutect2, varscan2
- ZNF592 | c.69C>T p.S23= | Silent (SNP) | VAF 128/268 reads (48%) | catalogued as rs757422555; called by muse, mutect2, varscan2
- ZSWIM1 | c.879G>A p.K293= | Silent (SNP) | VAF 134/391 reads (34%) | catalogued as rs775953832; called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130916361 C>T | 5'Flank (SNP) | VAF 120/387 reads (31%) | catalogued as rs1300881328; called by muse, mutect2
- ARHGEF4 | chr2:130916363 T>C | 5'Flank (SNP) | VAF 118/383 reads (31%) | called by muse, mutect2
- DSCR4 | n.130G>A | RNA (SNP) | VAF 83/282 reads (29%) | called by muse, mutect2, varscan2
- ENDOV | c.229-2207C>T | Intron (SNP) | VAF 50/511 reads (10%) | catalogued as rs1448609517; called by muse, mutect2
- KCNQ1 | c.1394-16002G>A | Intron (SNP) | VAF 137/266 reads (52%) | called by muse, mutect2, varscan2
- KCTD1 | c.-15-46087T>C | Intron (SNP) | VAF 77/272 reads (28%) | called by muse, mutect2, varscan2
- LIMK2 | c.1772+1487C>T | Intron (SNP) | VAF 210/508 reads (41%) | catalogued as rs780806196; called by mutect2, varscan2
- LINC00968 | n.232T>G | RNA (SNP) | VAF 52/295 reads (18%) | called by muse, mutect2, varscan2
- OBSCN | c.18662-2380G>A | Intron (SNP) | VAF 83/630 reads (13%) | called by muse, mutect2, varscan2
- SGIP1 | c.1571-935C>T | Intron (SNP) | VAF 43/302 reads (14%) | called by muse, mutect2, varscan2
- SORBS1 | c.2128+845C>T | Intron (SNP) | VAF 82/253 reads (32%) | called by muse, mutect2, varscan2
- TRIM41 | c.-677G>T | 5'UTR (SNP) | VAF 94/314 reads (30%) | called by muse, varscan2
- TSLP | chr5:111071511 G>A | 5'Flank (SNP) | VAF 92/313 reads (29%) | called by muse, mutect2, varscan2
- TTN | c.10361-4557C>T | Intron (SNP) | VAF 150/369 reads (41%) | catalogued as COSV100606647; called by muse, mutect2, varscan2
- WTAP | c.452+264G>A | Intron (SNP) | VAF 36/312 reads (12%) | called by muse, mutect2
- ZNF415 | c.-194-967C>T | Intron (SNP) | VAF 55/400 reads (14%) | called by muse, mutect2, varscan2
